Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A43H, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A43H-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAT TYPE:

PAGE #:

4

SEX:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Source of Specimen: Esophagus. Progressive dysphagia. Endoscopy revealed a mass with biopsy indicating moderately to poorly differentiated invasive squamous cell carcinoma. Clinical Diagnosis: See above. Operative Procedure/Tissue Submitted:

PROCEDURE: SPGD

VERIFIED BY:

1. "Esophageal margin." Received fresh for frozen section in a small container are two, red, soft tissue bits, 0.4 cm each. Frozen section control.
2. "Esophageal tumor, shave." Received fresh for frozen section in a small container is a 0.5 cm, red, soft tissue bit. Frozen section control.
3. "Aortic margin." Received fresh for frozen section in a small container is a 1.1 cm, red, soft tissue fragment. Frozen section control.
4. "Aortic wall." Received fresh for frozen section in a small container is a 0.5 cm, red, soft tissue bit. Frozen section control.
5. "Proximal stomach, distal esophagus, freeze cervical margin." Staple line removed. Surgical margin submitted. This portion is 13.8 cm, of which 10.4 cm is esophagus. The proximal and distal margins are stapled and there is a small amount of attached perigastric fat. The adventitia is focally adhered, mainly near the proximal margin. This area is inked blue. The proximal esophageal mucosa is red-tan to brown, granular and ulcerated. This area involves up to 3.2 cm from the stapled margin. The cut surface through this area is gray-white, firm and thickened up to 0.6 cm. The gray-white, firm tissue has an ill-defined pattern that extends to within 0.1 cm of the inked adventitia. The ill-defined extension makes it difficult to examine, yet it appears that it does involve the adventitia and adherent fibromembranous tissue. The distal 7.4 cm of the esophageal mucosa is unremarkable, as well as the adherent proximal gastric tissue. Within the perigastric fat are lymph node candidates up to 1.1 cm in greatest dimension.
- 5A-B. Frozen section control, cervical margin.
- 5C-D. Tumor to uninvolved esophagus.
- 5E-F. Deep penetration of tumor.
- 5G. Esophagogastric junction.
- 5H. Eleven whole lymph node candidates.
- 5I. Eight whole lymph node candidates. Fat retained.
6. "Cervical margin." Additional 1.5 cm length of esophagus with staple line.

ICD-O3

Carcinoma, Squamous cell, NOS
8070/3

Site:

CACF: esophagus, middle third
C15.4

PATH: esophagus, NOS
C15.9

8-20-12
20

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 5

SEX: [REDACTED]

PAT TYPE: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

Staple line removed.

6A. Frozen section control true margin.

6B. Frozen section control additional section below the margin (20 more mucosa).

7. "Paratracheal lymph node 4R lymph node" Received in formalin in a small container are two black-gray possible lymph nodes, 1.7 and 1.5 cm.

8. "Station 8 lymph node" Received in formalin in a small container are two possible lymph nodes, 0.5 and 1.6 cm.

FROZEN SECTION REPORT

1. Clusters of benign glands, favor heterotopia.
2. Negative for carcinoma.
- 3-4. Fibrosis and fat necrosis, negative for neoplasm.
- 5A-B. Cervical esophageal margin positive for invasive squamous cell carcinoma.
- 6A-B. Negative for carcinoma.

I, [REDACTED], have reviewed and interpreted the frozen section material at the time it was requested.

I, [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

I, [REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections do not confirm frozen section reports for part 2. Deeper sections reveal squamous cell carcinoma that was not present on the original frozen section slides (sampling error). notified via email on

PROCEDURE: SPMI

VERIFIED BY: [REDACTED]

ESOPHAGUS CARCINOMA

LOCATION: Esophagus, upper and middle.

SIZE: 3.2 cm.

HAS IT BEEN TREATED PREOPERATIVE WITH CHEMO/RADIATION THERAPY?: No.

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 6

PATIENT NBR: [REDACTED]
PAT TYPE: [REDACTED]

SEX: [REDACTED]

ACCESSION: [REDACTED]

OPER DATE: [REDACTED]

REQ DOC: [REDACTED]

TYPE OF CARCINOMA: Squamous cell carcinoma, typical.

DEPTH OF INVASION: Adventitia.

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 2/23.

DISTANT METASTASIS: Unknown.

RESECTION MARGIN INVOLVED: Yes, deep adventitial margin.

pT3 N1

PROCEDURE: SPDX

VERIFIED BY: [REDACTED]

1-6. Esophagus, resections: Invasive squamous cell carcinoma (3.2 cm), invading into esophageal adventitia. Deep adventitial resection margin positive for carcinoma. Cervical resection margin negative for carcinoma. Eighteen lymph nodes negative for carcinoma. Please see TEMPLATE.

7. Lymph node, paratracheal 4R, resection: Three lymph nodes negative for carcinoma.

8. Lymph node, station 8, resection: Metastatic squamous cell carcinoma involving two of two lymph nodes.

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file 16094f8a-0468-497c-b085-8a0bedad31d2 (TCGA-L5-A43H.05E43902-C6B2-4B94-8E10-8490FBFF33B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).